Somatic mutation profile of tumor specimen 0DNFU5 from CCDI case PBBYYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (619 days).
Specimen 0DNFU5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6fd1010-df68-4f7d-a0d7-3ab6bc87b7c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNFTV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07633761-833c-4ff4-98ca-547fc635154b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPDEF | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55062095; called by muse, mutect2
- IRS1 | c.1767G>T p.M589I | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
